Somatic mutation profile of tumor specimen TCGA-AB-2863-03D (aliquot TCGA-AB-2863-03D-01W-0755-09) from TCGA case TCGA-AB-2863, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,132 days).
Specimen TCGA-AB-2863-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4813f6e5-b2f4-404d-b0f7-06829d9efb31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2863-11B (Solid Tissue Normal), aliquot TCGA-AB-2863-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45d38ed5-b1b4-447e-8a8b-bf9457b5e061

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD9 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as COSV100614565; called by muse, mutect2, varscan2
